Somatic mutation profile of cancer-model specimen HCM-BROD-0036-C41-85A (Mixed Adherent Suspension, passage 12; aliquot HCM-BROD-0036-C41-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0036-C41, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ewing sarcoma; Tissue or organ of origin: Bone, NOS; Age at diagnosis: 13.7 years (4,997 days).
Specimen HCM-BROD-0036-C41-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 400171a3-3aae-41bd-9772-26f00e1d13fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0036-C41-10A (Blood Derived Normal), aliquot HCM-BROD-0036-C41-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8c47ce5-b69e-41ad-ad6c-d60e6cc72044

The open-access MAF lists 88 somatic variants for this specimen: 61 protein-altering or splice-affecting, 15 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 15, Intron 7, Frame Shift Del 6, Nonsense Mutation 4, 3'UTR 2, Splice Site 1, RNA 1, In Frame Del 1, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 152/303 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.273G>A p.W91* | Nonsense Mutation (SNP) | VAF 141/309 reads (46%) | hotspot (GDC flag); catalogued as rs876660548, CM065495, COSV52673580; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAD1 | c.117G>C p.W39C | Missense Mutation (SNP) | VAF 110/233 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV56644907; called by muse, mutect2, varscan2
- APOA4 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs184083285; called by muse, mutect2
- CELSR2 | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 90/175 reads (51%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.822); catalogued as COSV54769425; called by muse, mutect2, varscan2
- CNGA4 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202065874, COSV66005056; called by muse, mutect2, varscan2
- COL17A1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 215/473 reads (45%) | catalogued as rs1564685400, CM114989, COSV100793128; called by muse, varscan2
- DEAF1 | c.56_82del p.V19_A27del | In Frame Del (DEL) | VAF 123/307 reads (40%) | catalogued as rs768085739; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAH7 | c.7397G>A p.R2466H | Missense Mutation (SNP) | VAF 178/391 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770220298, COSV56756557, COSV56767044; called by muse, mutect2, varscan2
- FAAH | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 229/484 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs1321124174; called by muse, mutect2, varscan2
- GRM6 | c.1808T>C p.V603A | Missense Mutation (SNP) | VAF 123/269 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747287686; called by muse, mutect2, varscan2
- HNRNPU | c.2023G>T p.A675S (on ENST00000283179; = p.A737S on NM_004501.3) | Missense Mutation (SNP) | VAF 97/419 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV51694757; called by muse, mutect2, varscan2
- IGFLR1 | c.871C>A p.L291M | Missense Mutation (SNP) | VAF 272/273 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.441); catalogued as rs140797969; called by muse, mutect2, varscan2
- IL36A | c.415A>T p.I139F | Missense Mutation (SNP) | VAF 230/499 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52083843; called by muse, mutect2, varscan2
- KDM2B | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV65640595; called by muse, mutect2, varscan2
- MACROH2A2 | c.827G>T p.C276F | Missense Mutation (SNP) | VAF 122/243 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57159781; called by muse, mutect2, varscan2
- NEU2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52093247; called by muse, mutect2, varscan2
- OR1E1 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 215/509 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs763721339; called by muse, mutect2, varscan2
- PAX7 | c.1235G>A p.G412D | Missense Mutation (SNP) | VAF 230/455 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as rs1268130256; called by muse, mutect2, varscan2
- PCDHGB2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 323/662 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV54043492; called by muse, mutect2, varscan2
- POPDC3 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 130/295 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs369322692; called by muse, mutect2, varscan2
- PRSS21 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 222/431 reads (52%) | catalogued as rs769176365; called by muse, mutect2, varscan2
- RYR3 | c.4801C>T p.L1601F | Missense Mutation (SNP) | VAF 103/272 reads (38%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.925); catalogued as COSV66803562; called by muse, mutect2, varscan2
- SAMD8 | c.1219C>G p.P407A | Missense Mutation (SNP) | VAF 64/109 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.441); catalogued as rs1325826383; called by muse, mutect2, varscan2
- SAMD9L | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 182/546 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59082965; called by muse, mutect2, varscan2
- SLC35G1 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); catalogued as rs1005579535; called by muse, mutect2, varscan2
- SNAP25 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs774645750, COSV54776523; called by muse, mutect2, varscan2
- STAG2 | c.2594T>G p.L865R | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54364299; called by muse, mutect2, varscan2
- TEKT1 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 105/214 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs1323028482, COSV58622482; called by muse, mutect2, varscan2
- TSPAN33 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.142); catalogued as COSV56827704, COSV56827816; called by muse, mutect2, varscan2
- USP2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 104/388 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs770297090, COSV52730427, COSV52730591; called by mutect2, varscan2
- ANO3 | c.1956_1962del p.F654Sfs*9 | Frame Shift Del (DEL) | VAF 44/167 reads (26%) | called by mutect2, pindel, varscan2
- BBS12 | c.1828T>G p.S610A | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CTNND2 | c.3119C>G p.S1040C | Missense Mutation (SNP) | VAF 155/345 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- DDX60L | c.4983_4985delinsTT p.Q1661Hfs*7 | Frame Shift Del (DEL) | VAF 14/91 reads (15%) | called by pindel, varscan2*
- DNAH6 | c.8981G>A p.G2994E | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EBF1 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EBF1 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FAAP100 | c.2596_2605del p.L866Cfs*76 | Frame Shift Del (DEL) | VAF 84/324 reads (26%) | called by mutect2, pindel*, varscan2*
- FLG2 | c.6827A>G p.Q2276R | Missense Mutation (SNP) | VAF 184/603 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.127); called by muse, varscan2
- HDGF | c.490-10_491del p.X164_splice | Splice Site (DEL) | VAF 23/269 reads (9%) | called by pindel, varscan2*
- KEL | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 21/702 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.107); called by muse, mutect2
- KRT6B | c.1562T>G p.L521R | Missense Mutation (SNP) | VAF 270/789 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NBEAL1 | c.395del p.S132Tfs*18 | Frame Shift Del (DEL) | VAF 56/140 reads (40%) | called by mutect2, pindel, varscan2
- NECTIN1 | c.1063G>C p.A355P | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10A5 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- OR11H1 | c.576T>G p.D192E | Missense Mutation (SNP) | VAF 91/250 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.007); called by mutect2, varscan2
- OR11H12 | c.312A>C p.K104N | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by mutect2, varscan2
- OR2T10 | c.515A>G p.H172R | Missense Mutation (SNP) | VAF 126/532 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR52W1 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 188/563 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- OS9 | c.347A>G p.D116G | Missense Mutation (SNP) | VAF 146/313 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHBG | c.454del p.L152Cfs*25 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- ROS1 | c.1901T>C p.L634P | Missense Mutation (SNP) | VAF 195/391 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SH3PXD2A | c.28_32del p.T10Gfs*23 | Frame Shift Del (DEL) | VAF 74/183 reads (40%) | called by mutect2, pindel, varscan2
- TCN1 | c.1003T>A p.S335T | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- TMEM9B | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 122/423 reads (29%) | called by muse, mutect2, varscan2
- TRIM77 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, varscan2
- TTC28 | c.773dup p.Q259Afs*11 | Frame Shift Ins (INS) | VAF 44/203 reads (22%) | called by mutect2, pindel, varscan2
- UBN2 | c.4034A>T p.K1345I | Missense Mutation (SNP) | VAF 219/366 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFY | c.1514T>C p.V505A | Missense Mutation (SNP) | VAF 289/408 reads (71%) | SIFT tolerated (0.26); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ZNF462 | c.226A>T p.N76Y | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.123); called by muse, mutect2
- CHST9 | c.181T>C p.L61= | Silent (SNP) | VAF 46/211 reads (22%) | called by muse, mutect2, varscan2
- FGF18 | c.279C>T p.F93= | Silent (SNP) | VAF 22/410 reads (5%) | catalogued as rs375630229; called by muse, mutect2
- GGT1 | c.1446A>T p.A482= | Silent (SNP) | VAF 540/1107 reads (49%) | called by muse, mutect2, varscan2
- HS3ST1 | c.378G>A p.S126= | Silent (SNP) | VAF 17/217 reads (8%) | catalogued as rs190695013, COSV50025408; called by muse, mutect2
- MAST4 | c.1408C>A p.R470= (on ENST00000403625 / NM_001164664.2; = p.R281= on NM_015183.3) | Silent (SNP) | VAF 81/204 reads (40%) | catalogued as COSV55121118; called by muse, mutect2, varscan2
- MUC5AC | c.14268A>G p.V4756= | Silent (SNP) | VAF 196/431 reads (45%) | catalogued as rs946035588; called by muse, mutect2, varscan2
- OR5T3 | c.588C>A p.L196= | Silent (SNP) | VAF 88/265 reads (33%) | catalogued as rs374751770, COSV57380253; called by muse, mutect2, varscan2
- PIK3C2G | c.4197C>T p.G1399= (on ENST00000676171; = p.G1358= on NM_004570.5) | Silent (SNP) | VAF 120/265 reads (45%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.2007C>A p.S669= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV67588484; called by muse, mutect2, varscan2
- RHD | c.312G>T p.G104= | Silent (SNP) | VAF 263/722 reads (36%) | called by muse, mutect2, varscan2
- SCARA5 | c.1008G>T p.G336= | Silent (SNP) | VAF 121/206 reads (59%) | called by muse, mutect2, varscan2
- TJP1 | c.1122A>G p.R374= | Silent (SNP) | VAF 41/98 reads (42%) | called by muse, mutect2, varscan2
- TMEM11 | c.297G>A p.L99= | Silent (SNP) | VAF 81/179 reads (45%) | catalogued as rs1442295946; called by muse, mutect2, varscan2
- VPS37D | c.237G>A p.R79= | Silent (SNP) | VAF 215/601 reads (36%) | called by muse, mutect2, varscan2
- ZNF516 | c.1419G>A p.A473= | Silent (SNP) | VAF 173/262 reads (66%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1356G>T | RNA (SNP) | VAF 129/647 reads (20%) | catalogued as rs1553559316; called by muse, mutect2, varscan2
- C1orf141 | c.416+14A>T | Intron (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2, varscan2
- DEPDC4 | c.*452G>A | 3'UTR (SNP) | VAF 7/176 reads (4%) | catalogued as rs1272396990; called by muse, mutect2
- DGLUCY | c.257+150del | Intron (DEL) | VAF 200/682 reads (29%) | catalogued as COSV99823910; called by mutect2, pindel, varscan2
- EIF4E | c.*36G>A | 3'UTR (SNP) | VAF 10/196 reads (5%) | catalogued as rs1221893529; called by muse, mutect2
- MOGS | c.777-25T>A | Intron (SNP) | VAF 14/350 reads (4%) | called by muse, mutect2
- MYLPF | c.-30C>T | 5'UTR (SNP) | VAF 84/208 reads (40%) | catalogued as COSV104394598; called by muse, mutect2, varscan2
- PMP22 | c.320-4142C>T | Intron (SNP) | VAF 13/200 reads (7%) | catalogued as rs976316377; called by muse, mutect2
- RN7SL484P | chr15:99792683 C>T | 3'Flank (SNP) | VAF 80/303 reads (26%) | called by muse, varscan2
- TNNT2 | c.234-23C>G | Intron (SNP) | VAF 169/370 reads (46%) | called by muse, mutect2, varscan2
- TNNT2 | c.234-24G>T | Intron (SNP) | VAF 170/368 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.10360+1160A>G | Intron (SNP) | VAF 24/69 reads (35%) | catalogued as rs1405282268; called by muse, mutect2, varscan2
